Gene-level copy-number profile of tumor specimen TCGA-2G-AAKG-05A from TCGA case TCGA-2G-AAKG, project TCGA-TGCT (Testicular Germ Cell Tumors). Sex at birth: male; Vital status: Alive; Primary diagnosis: Embryonal carcinoma, NOS; Tissue or organ of origin: Testis, NOS; AJCC pathologic stage: Stage I; Age at diagnosis: 22.9 years (8,353 days).
Specimen TCGA-2G-AAKG-05A: Sample type: Additional - New Primary; Tissue type: Tumor; Tumor descriptor: New Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-TGCT.6ebc0a1b-af63-42a9-beba-90778adec063.gene_level_copy_number.v36.tsv, workflow ASCAT2 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-2G-AAKG-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 360 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/1e71d022-ec0a-41f3-b7ab-9c630de11f58

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 2,385; copy number 1: 2,904; copy number 2: 18,022; copy number 3: 22,199; copy number 4: 10,303; copy number 5: 3,426; copy number 6: 749; copy number 7: 250; copy number 8: 4; copy number 13: 21.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-2G-AAKG-05A-11D-A42X-01): tumor purity 0.4, ploidy 2.78, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 5 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:53,286–88,208, 1 gene: ZNF595.
- chr5:180,967,189–181,006,727, 4 genes (within-gene range 0–2): AC091874.2, AC091874.1, ARPP19P1, BTNL3.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 275 genes in 7 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:88,811,186–88,861,563, 1 gene, copy number 13 (within-gene range 4–13): AC244205.1.
- chr2:88,857,161–89,046,466, 20 genes, copy number 13: IGKC, IGKJ5, IGKJ4, IGKJ3, IGKJ2, IGKJ1, IGKV4-1, IGKV5-2, IGKV7-3, PGBD4P5, IGKV2-4, IGKV1-5, IGKV1-6, IGKV3-7, IGKV1-8, IGKV1-9, IGKV2-10, IGKV3-11, IGKV1-12, IGKV1-13.
- chr7:69,507,510–70,838,013, 4 genes, copy number 8: Y_RNA, CT66, AUTS2, AC073873.1.
- chr7:77,122,434–97,599,260, 242 genes, copy number 7 (within-gene range 6–7) (broad region; genes not listed).
- chr13:19,026,001–19,032,626, 2 genes, copy number 7 (within-gene range 1–7): GTF2IP3, AL137001.1.
- chr17:46,029,916–46,225,389, 1 gene, copy number 7 (within-gene range 2–7): KANSL1.
- chr17:46,193,576–46,268,694, 5 genes, copy number 7: KANSL1-AS1, Y_RNA, MAPK8IP1P1, AC005829.2, AC005829.1.

Autosomal genes at a single copy (total copy number 1): 2,904. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
